Gene-level copy-number profile of tumor specimen ALCH-B03Z-TTP1-A from ALCHEMIST case ALCH-B03Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.8 years (25,134 days).
Specimen ALCH-B03Z-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 65c9e0d4-d778-4200-a384-893c4ac521c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B03Z-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/a2867399-5de6-4e54-8494-adcea4c19422

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 12,677; copy number 2: 41,834; copy number 3: 4,279; copy number 4: 81; copy number 5: 5; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:55,039,447–55,064,852, 1 gene: PCSK9.
- chr3:38,526,802–38,527,325, 1 gene (within-gene range 0–2): RPL18AP7.
- chr7:57,227,001–57,227,066, 1 gene: RNU7-157P.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.
- chr9:138,129,399–138,129,526, 1 gene: AL591424.1.
- chr17:2,017,716–2,023,664, 2 genes (within-gene range 0–1): AC099684.1, AC099684.3.
- chr17:2,724,411–2,749,504, 1 gene (within-gene range 0–1): CCDC92B.
- chr18:37,243,776–37,247,506, 1 gene (within-gene range 0–1): AC015961.2.
- chr19:1,275,530–1,279,244, 1 gene: FAM174C.
- chr19:5,865,826–5,870,540, 1 gene (within-gene range 0–1): FUT5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes, copy number 6 (within-gene range 2–6): PRAMEF6, PRAMEF28P.
- chr1:13,172,455–13,179,464, 1 gene, copy number 5: PRAMEF9.
- chr10:3,748,966–3,834,728, 4 genes, copy number 5: AL450322.2, AL450322.1, KLF6, LINC02639.

Autosomal genes at a single copy (total copy number 1): 9,828. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
